Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6940, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6940-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) LEFT BUCCAL MUCOSAL LESION:
DEEPLY INVASIVE, MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA.
- (B) SUPERIOR MARGIN:
Squamous mucosa, negative for carcinoma.
- (C) ANTERIOR MARGIN:
Squamous mucosa, negative for carcinoma.
- (D) INFERIOR MARGIN:
Squamous mucosa, negative for carcinoma.
- (E) LEFT NECK DISSECTION:
One of twelve lymph nodes, positive for metastatic carcinoma (1/12).

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

(A) LEFT BUCCAL MUCOSAL LESION - A mucosal lesion with overall measurements of 4.0 x 2.5 x 1.5 cm. The light-tan and firm slightly fungating lesion 3.3 x 1.5 x 1.2 cm is noted. A normal-appearing mucosa approximately 0.3 to 0.4 cm is noted around the tumor. The tumor abuts the deep margin. The specimen is submitted from anterior to posterior. The specimen is submitted sequentially from anterior to posterior under A1 and A2, for frozen; A3-A8, tumor and surrounding mucosa.

*FS/DX: POSTERIOR MARGIN, NO TUMOR PRESENT. DEEP MARGIN, NEGATIVE, BUT WITHIN 1.0 MM.

(B) SUPERIOR MARGIN - Two tan-pink fragments of mucosa 1.2 and 0.6 cm. Totally submitted in B.

*FS/DX: NEGATIVE FOR CARCINOMA.

(C) ANTERIOR MARGIN - A 2.5 x 0.5 x 0.3 cm segment also a linear fragment of tan-pink mucosa that is grossly unremarkable. Totally submitted for frozen section as C.

*FS/DX: NEGATIVE FOR CARCINOMA.

(D) INFERIOR MARGIN - A 3.2 x 0.6 x 0.3 cm linear segment of tan-pink mucosa that is grossly unremarkable. Totally submitted for frozen section as D.

*FS/DX: NEGATIVE FOR CARCINOMA.

(E) LEFT NECK DISSECTION (SPECIMEN IS ORIENTED BY THE SURGEON) - Left neck level I measuring 5.0 x 5.0 x 1.5 cm. A submandibular gland (4.0 x 2.5 x 1.0 cm). Identified is one lymph node, 0.5 x 0.5 x 0.4 cm.

Level II measuring 8.0 x 5.0 x 1.5 cm. A fascia of skeletal muscle, 8.0 x 4.0 cm. Identified are three lymph nodes ranging in size from 0.2 x 0.2 x 0.2 cm to 0.4 x 0.4 x 0.3 cm.

Level III measuring 4.0 x 4.0 x 1.5 cm. A fascia of skeletal muscle, 3.0 x 3.0 cm. Identified are four lymph nodes ranging in size from 0.2 x 0.2 x 0.2 cm to 0.3 x 0.2 x 0.2 cm.

[page 2 of 2]
[REDACTED]

Level IV measuring 4.0 x 2.5 x 1.0 cm. Identified are five lymph nodes ranging in size from 0.3 x 0.2 x 0.2 cm to 0.7 x 0.3 x 0.3 cm.

Level V measuring 3.0 x 2.0 x 1.0 cm. Identified is one possible lymph node, 0.4 x 0.4 x 0.2 cm.

SECTION CODE: Level I: E1, representative sections of submandibular gland; E2, one lymph node bisected. Level II: E3, representative sections of skeletal muscle; E4, three lymph nodes. Level III: E5, representative sections of muscle; E6, four lymph nodes. Level IV: E7, five possible lymph nodes. Level V: E8, one possible lymph node. [REDACTED]

CLINICAL HISTORY

None given.

[REDACTED]

Released by: [REDACTED]

Source: NCI Genomic Data Commons file c820c01b-5915-4905-91b7-1eda2fd30691 (TCGA-CV-6940.719411CB-928B-4BF7-8A26-6A45C0FC26A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).